Gene-level copy-number profile of tumor specimen TCGA-AR-A24Z-01A from TCGA case TCGA-AR-A24Z, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 57.2 years (20,900 days).
Specimen TCGA-AR-A24Z-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.712486dc-9fc5-4e76-85ae-34a1e35120b5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AR-A24Z-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2f01e54d-02ce-4ccb-9878-88f8fa7ddfeb

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 51; copy number 1: 2,297; copy number 2: 9,897; copy number 3: 26,525; copy number 4: 16,145; copy number 5: 1,741; copy number 6: 1,828; copy number 7: 467; copy number 8: 289; copy number 9: 261; copy number 10: 153; copy number 11: 46; copy number 12: 2; copy number 13: 107; copy number 14: 2; copy number 15: 1; copy number 17: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AR-A24Z-01A-11D-A166-01): tumor purity 0.81, ploidy 3.24, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 51 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:181,064,089–181,591,969, 5 genes (within-gene range 0–1): LINC00290, AC019235.1, LINC02500, AC093840.1, AC093840.2.
- chr9:8,700,595–9,442,380, 7 genes: AL583805.2, AL583805.1, RNU7-185P, PTPRD-AS1, AL596451.1, RPS26P3, RN7SL5P.
- chr9:21,802,636–22,029,594, 2 genes (within-gene range 0–2): MTAP, AL359922.1.
- chr9:21,858,910–26,118,408, 37 genes: AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3, AL513317.1, IZUMO3, AL353811.1, RMRPP5, RN7SKP120, AL353730.1, TUSC1, LINC01241, FAM71BP1, AL353753.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,329 genes in 32 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:30,810,378–32,703,596, 75 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr1:52,142,094–56,826,920, 135 genes, copy number 8 (within-gene range 5–8) (broad region; genes not listed).
- chr1:56,994,778–58,546,734, 8 genes, copy number 8 (within-gene range 5–8): DAB1, AL390243.1, RPS20P5, DAB1-AS1, HNRNPA1P6, RPS26P15, AL445193.2, AL445193.1.
- chr1:58,882,868–64,267,368, 87 genes, copy number 9–17 (broad region; genes not listed).
- chr1:65,057,755–66,988,619, 27 genes, copy number 9: MIR3671, MIR101-1, AL357078.1, MRPS21P1, AK4, RPS29P7, DNAJC6, AL139294.1, COX6CP13, RNU2-15P, LEPROT, LEPR, AC119800.1, AC097063.1, AL513493.1, RN7SL854P, PDE4B, PDE4B-AS1, RNU4-88P, SGIP1, MIR3117, AL139147.1, TCTEX1D1, INSL5, DNAI4, AL592161.1, MIER1.
- chr1:72,274,552–73,355,253, 11 genes, copy number 7: GDI2P2, AL513166.1, RPL31P12, AL583808.1, RNU6-1246P, LINC02796, LINC02797, AL732618.1, KRT8P21, RN7SKP19, LINC01360.
- chr1:75,786,197–76,066,349, 8 genes, copy number 8: RABGGTB, SNORD45C, SNORD45A, SNORD45B, MSH4, ASB17, AC092813.1, AC092813.2.
- chr1:158,327,951–158,579,899, 15 genes, copy number 9: CD1B, CD1E, OR10T2, OR10K2, OR10T1P, EI24P2, OR10K1, OR10R2, AL365440.1, OR10R3P, OR10R1P, HSP90AA3P, OR6Y1, OR6P1, OR10X1.
- chr1:159,899,979–162,446,566, 122 genes, copy number 9 (broad region; genes not listed).
- chr1:176,857,302–177,920,152, 6 genes, copy number 8 (within-gene range 2–8): ASTN1, MIR488, BRINP2, LINC01645, AL136114.1, LINC01741.
- chr1:178,194,342–178,194,709, 1 gene, copy number 9: AL160281.1.
- chr1:178,725,147–181,808,084, 63 genes, copy number 8 (within-gene range 2–8) (broad region; genes not listed).
- chr1:188,508,538–188,536,465, 1 gene, copy number 8: AL929288.1.
- chr1:190,781,787–192,185,815, 10 genes, copy number 9: AL139135.1, AL139135.2, AL138927.1, HNRNPA1P46, AL713866.1, AL713866.2, LINC01680, LINC02770, AL359081.1, RGS18.
- chr1:192,246,708–192,367,285, 3 genes, copy number 9: AL513175.1, AL513175.2, RGS21.
- chr1:197,685,640–199,393,307, 26 genes, copy number 7: Y_RNA, EEF1A1P32, AL365258.2, FAM204BP, AL365258.1, C1orf53, LHX9, NEK7, PRR13P1, AL450352.1, ATP6V1G3, AL157402.1, PTPRC, AL157402.2, PEBP1P3, MIR181A1HG, MIR181B1, MIR181A1, AC096631.2, AC096631.1, LINC01222, LINC01221, AC105941.1, LINC02789, RPL23AP16, AC099335.1.
- chr1:201,622,885–201,826,969, 1 gene, copy number 7 (within-gene range 4–7): NAV1.
- chr1:201,688,259–201,829,559, 1 gene, copy number 7 (within-gene range 4–7): IPO9-AS1.
- chr1:201,723,294–208,270,667, 216 genes, copy number 7–14 (broad region; genes not listed).
- chr1:209,528,455–214,552,449, 107 genes, copy number 8–15 (within-gene range 6–15) (broad region; genes not listed).
- chr1:215,005,775–215,621,807, 4 genes, copy number 10: KCNK2, VDAC1P10, AL450990.1, KCTD3.
- chr1:215,630,026–215,630,117, 1 gene, copy number 10: SNORD116.
- chr1:216,503,246–217,631,090, 2 genes, copy number 12: ESRRG, GPATCH2.
- chr1:231,925,834–232,751,299, 9 genes, copy number 7: DISC1-IT1, AL353052.1, AL353052.2, BX323014.1, RN7SL299P, SIPA1L2, RNU6-1211P, LINC01745, LINC01744.
- chr1:232,983,435–233,295,725, 1 gene, copy number 8 (within-gene range 2–8): PCNX2.
- chr4:185,585,444–185,956,652, 1 gene, copy number 7 (within-gene range 3–7): SORBS2.
- chr4:185,709,873–186,500,997, 16 genes, copy number 7 (within-gene range 3–7): Y_RNA, AC104805.1, AC096659.1, RNU4-64P, TLR3, FAM149A, AC104070.1, RPSAP70, ORAOV1P1, FLJ38576, CYP4V2, KLKB1, F11, F11-AS1, AC109517.1, SLC25A5P6.
- chr6:44,809,317–46,170,980, 14 genes, copy number 8: SUPT3H, NUDT19P4, AL138880.2, RBM22P4, AL138880.1, MIR586, RUNX2, AL096865.1, RUNX2-AS1, CLIC5, RNU6-754P, AL035701.1, ENPP4, ENPP5.
- chr6:47,656,436–49,116,115, 16 genes, copy number 7: ADGRF2, ADGRF4, RN7SKP116, AL356421.2, AL356421.1, OPN5, RNU1-105P, PTCHD4, AL353138.1, HNRNPA3P4, RBMXP1, FO393412.1, AL391538.1, AL022099.1, AL589994.1, AL589994.2.
- chr6:72,522,641–73,452,297, 26 genes, copy number 7: FO393414.2, FO393414.1, FO393414.3, KCNQ5, MIR4282, KNOP1P4, PGAM1P10, KCNQ5-AS1, RBPMS2P1, KHDC1P1, AL365232.1, KHDC1L, KHDC1, AC019205.1, RPSAP41, EIF3EP1, SDCBP2P1, PAICSP3, DPPA5, KHDC3L, OOEP, OOEP-AS1, RPL39P3, RPS6P8, DDX43, CGAS.
- chr6:85,949,690–88,442,928, 48 genes, copy number 9–10: AL450338.2, RNU4-12P, RPL7P27, RAB1AP2, NDUFA5P9, AL391417.1, RN7SL643P, AL353133.1, AL353133.2, AL157777.1, AL157777.2, HTR1E, RPL7P29, MTHFD2P2, AL138827.1, RN7SKP209, CGA, RCN1P1, AL139274.2, ZNF292, AL139274.1, GJB7, HSPD1P10, SMIM8, C6orf163, AL096817.1, CFAP206, AL049697.1, AL049697.2, AL049697.3, ST13P16, SLC35A1, RNU6-444P, RARS2, ORC3, AKIRIN2, AL133211.1, Y_RNA, RN7SL183P, AL590392.1, AL136096.1, SPACA1, CNR1, AL121835.2, AL139042.1, AL121835.1, ACTBP8, AL139090.1.
- chr11:69,481,662–77,637,794, 268 genes, copy number 7–8 (within-gene range 2–8) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,297. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
